Somatic mutation profile of tumor specimen 0DOLVB from CCDI case PBCCKA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 16.9 years (6,160 days).
Specimen 0DOLVB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1761c29b-02a7-4699-ae17-3e0725a22fdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab6101d0-113b-44dc-849e-b0d588ca8a6e

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Nonsense Mutation 2, Silent 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 26/726 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- BDNF | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 25/906 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.203); catalogued as rs1295890250, COSV59232895; called by muse, mutect2
- HNRNPCL2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 40/1194 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as rs772495936; called by muse, mutect2
- TRMT10C | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 24/690 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59306778; called by muse, mutect2
- ANGPT2 | c.1457C>T p.A486V | Missense Mutation (SNP) | VAF 18/618 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.414); called by muse, mutect2
- DDX20 | c.823+8C>T | Splice Region (SNP) | VAF 23/489 reads (5%) | called by muse, mutect2
- EVX1 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRIA1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 25/868 reads (3%) | called by muse, mutect2
- MLX | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 19/556 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2
- NBEA | c.2426C>G p.T809R | Missense Mutation (SNP) | VAF 24/551 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PDE12 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 32/900 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2
- PPP4R3A | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 12/392 reads (3%) | called by muse, mutect2
- PSAPL1 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 24/575 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ABR | c.378C>T p.L126= | Silent (SNP) | VAF 22/761 reads (3%) | catalogued as rs1567908576; called by muse, mutect2
- NRBP2 | c.246G>A p.A82= | Silent (SNP) | VAF 32/434 reads (7%) | catalogued as rs1357796997; called by muse, mutect2
- BEST3 | c.248-44G>C | Intron (SNP) | VAF 5/148 reads (3%) | catalogued as rs866225950; called by muse, mutect2
- EPHA3 | c.1594+39G>A | Intron (SNP) | VAF 18/349 reads (5%) | catalogued as COSV100342127; called by muse, mutect2
- FNDC11 | c.*1G>C | 3'UTR (SNP) | VAF 14/394 reads (4%) | called by muse, mutect2
- MLX | c.539-64C>G | Intron (SNP) | VAF 18/318 reads (6%) | called by muse, mutect2
